Somatic mutation profile of tumor specimen TCGA-QH-A6X5-01A (aliquot TCGA-QH-A6X5-01A-12D-A32B-08) from TCGA case TCGA-QH-A6X5, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 58.1 years (21,239 days).
Specimen TCGA-QH-A6X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8453302c-5022-4ed4-8409-f1010edb5d23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6X5-10B (Blood Derived Normal), aliquot TCGA-QH-A6X5-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2d5a26d-0a9e-44cc-9336-62076b34b3b9

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Frame Shift Del 6, Silent 3, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- C2orf88 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100502664; called by muse, mutect2, varscan2
- CDK12 | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs773007495, COSV71002489; called by muse, mutect2, varscan2
- CENPI | c.1603A>G p.K535E | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99514944; called by muse, mutect2, varscan2
- CIC | c.778C>G p.H260D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV50663864, COSV99358726; called by muse, mutect2, varscan2
- EDEM3 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV100544788; called by muse, mutect2
- FAM83G | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100524709; called by muse, mutect2, varscan2
- GIMAP8 | c.1667_1668del p.F556Yfs*28 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as rs768280930; called by mutect2, pindel, varscan2
- IPO11 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs775269043, COSV100320167; called by muse, mutect2, varscan2
- KAT6B | c.3058_3060del p.K1020del | In Frame Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs772535828; called by mutect2, pindel, varscan2
- LILRB2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs879175011, COSV100078870; called by muse, mutect2
- LRBA | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs779175495, COSV100840787; called by muse, mutect2, varscan2
- PDHA1 | c.613T>A p.F205I | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100133883; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 26/107 reads (24%) | catalogued as rs782753958; called by mutect2, varscan2
- TMEM131L | c.1300A>G p.M434V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1275234451, COSV99546587; called by muse, mutect2, varscan2
- BCOR | c.2890_2891del p.K964Efs*11 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- CIC | c.4007del p.P1336Rfs*3 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- RASGRF2 | c.365_366del p.K122Rfs*17 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- TBC1D8B | c.3288del p.F1096Lfs*5 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- TMEM94 | c.1256_1257del p.Q419Rfs*28 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- ADH4 | c.993A>G p.V331= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99643961; called by muse, mutect2
- GLRA2 | c.15A>G p.L5= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV99490046; called by muse, mutect2, varscan2
- ODAM | c.165A>G p.P55= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs776688725, COSV101258012; called by muse, mutect2
